Somatic mutation profile of tumor specimen TCGA-D1-A17C-01A (aliquot TCGA-D1-A17C-01A-11D-A12J-09) from TCGA case TCGA-D1-A17C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 78.2 years (28,571 days).
Specimen TCGA-D1-A17C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7191d16b-eadc-43ab-aa46-1bd5423ed582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17C-10A (Blood Derived Normal), aliquot TCGA-D1-A17C-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7866959b-0893-4d5e-8cac-380788befd55

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 36, Silent 14, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 44/213 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 38/177 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 122/268 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF26 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1324480739, COSV62850712; called by muse, mutect2, varscan2
- ARID1A | c.3949G>T p.G1317W | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61385995; called by muse, mutect2, varscan2
- ASAH1 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50503712; called by muse, mutect2, varscan2
- ATP2A2 | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 53/200 reads (27%) | catalogued as COSV57875770, COSV57876130; called by muse, mutect2, varscan2
- CELSR1 | c.8893C>T p.R2965C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs370322773, COSV53097548; called by muse, mutect2, varscan2
- CHD3 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 25/116 reads (22%) | catalogued as COSV57879144; called by muse, mutect2, varscan2
- CLSTN1 | c.2509C>T p.R837C (on ENST00000377298 / NM_001009566.3; = p.R827C on NM_014944.4) | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1328461877, COSV63129394, COSV63131028; called by muse, mutect2, varscan2
- CYP2A6 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs374515279; called by muse, mutect2, varscan2
- DLGAP2 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs762050332, COSV70098404; called by muse, mutect2, varscan2
- EXOC6B | c.1106A>T p.Y369F | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1354447383, COSV55568027; called by muse, mutect2, varscan2
- GLB1L | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1207499779, COSV55478366; called by muse, mutect2, varscan2
- HELZ | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV62380350; called by muse, mutect2
- ING1 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58166764, COSV58172279; called by muse, mutect2, varscan2
- KDM4B | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50242830; called by muse, mutect2, varscan2
- MAOA | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58644818; called by muse, mutect2, varscan2
- MGA | c.7298G>T p.R2433L (on ENST00000219905 / NM_001164273.1; = p.R2224L on NM_001080541.2) | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54951840, COSV54960951; called by muse, mutect2, varscan2
- MIA3 | c.3442C>A p.L1148I | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV60516618; called by muse, mutect2, varscan2
- MTOR | c.7571A>T p.Q2524L | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63875858; called by muse, mutect2
- MTPAP | c.1735A>T p.S579C | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV53935488; called by muse, mutect2, varscan2
- MYH14 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1252157393, COSV51828380; called by muse, mutect2, varscan2
- MYO18B | c.5440G>A p.V1814M | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs767004218, COSV59144630; called by muse, mutect2, varscan2
- NAP1L1 | c.72_74del p.E26del | In Frame Del (DEL) | VAF 65/356 reads (18%) | catalogued as rs922184331; called by pindel, varscan2
- NAV3 | c.6227A>C p.K2076T (on ENST00000397909 / NM_001024383.2; = p.K2054T on NM_014903.6) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV57104926; called by muse, mutect2, varscan2
- NMUR1 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs766397486, COSV59405447; called by muse, mutect2, varscan2
- OR4D10 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs200781301; called by muse, mutect2, varscan2
- OR6T1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58307012; called by muse, mutect2, varscan2
- PKP4 | c.672T>A p.Y224* | Nonsense Mutation (SNP) | VAF 38/177 reads (21%) | catalogued as COSV67678857; called by muse, mutect2, varscan2
- RAD50 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV54756396; called by muse, mutect2, varscan2
- RBBP6 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs367639774; called by muse, mutect2, varscan2
- RBM33 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.519); catalogued as rs1461425008, COSV56636264; called by muse, mutect2, varscan2
- RNF31 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 48/173 reads (28%) | catalogued as COSV60728100; called by muse, mutect2, varscan2
- SLC2A4 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as rs916772432, COSV50301190; called by muse, mutect2, varscan2
- SLC35F5 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.596); catalogued as COSV55520070; called by muse, mutect2, varscan2
- SYTL5 | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV52904490; called by muse, mutect2
- TOP1MT | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs747566486, COSV61319405; called by muse, mutect2, varscan2
- TSGA10IP | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV73245396; called by muse, mutect2, varscan2
- WNT9A | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs777039521, COSV55296649; called by muse, mutect2, varscan2
- ZNF701 | c.231G>T p.R77S (on ENST00000301093; = p.R11S on NM_018260.3) | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV99990914; called by muse, mutect2
- ARID1A | c.3791_3803del p.A1264Efs*21 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by mutect2, pindel
- ARID1A | c.4540_4550del p.T1514Pfs*14 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- COL1A1 | c.2216del p.P739Qfs*27 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1675_1693del p.I559Afs*9 (on ENST00000521381 / NM_181523.3; = p.I289Afs*9 on NM_181504.4) | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | called by pindel, varscan2
- SIM1 | c.751_753del p.E251del | In Frame Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- TCOF1 | c.1578del p.K528Rfs*68 (on ENST00000377797 / NM_001135243.1; = p.K451Rfs*68 on NM_000356.4) | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- ANKRD52 | c.1941G>A p.K647= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV57286682; called by muse, mutect2, varscan2
- CDHR5 | c.399G>A p.V133= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV51564867; called by muse, mutect2, varscan2
- FRMPD4 | c.3096C>T p.A1032= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs1026491715, COSV66220263; called by muse, mutect2
- GAS2L3 | c.1075C>T p.L359= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV57158712; called by muse, mutect2, varscan2
- IGHV1-58 | c.330G>A p.T110= | Silent (SNP) | VAF 51/202 reads (25%) | catalogued as rs369415219; called by muse, mutect2, varscan2
- ITGB3 | c.474G>A p.Q158= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV71385040; called by muse, mutect2, varscan2
- MAGEA11 | c.624G>A p.S208= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as rs782565753, COSV100290720, COSV60758049; called by muse, mutect2, varscan2
- POU4F2 | c.1077G>A p.S359= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs746344869, COSV55583836, COSV55584848; called by muse, mutect2, varscan2
- PRRC2C | c.5583C>G p.A1861= (on ENST00000367742; = p.A1859= on NM_015172.4) | Silent (SNP) | VAF 92/373 reads (25%) | catalogued as COSV58911282; called by muse, mutect2, varscan2
- RASGRF2 | c.864C>T p.D288= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs368702145; called by muse, mutect2, varscan2
- SLC30A9 | c.858C>T p.G286= | Silent (SNP) | VAF 78/431 reads (18%) | catalogued as rs1346270112, COSV52558551; called by muse, mutect2, varscan2
- SLC7A13 | c.309G>T p.L103= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as COSV52535490, COSV52536488; called by muse, mutect2, varscan2
- SRPK3 | c.216C>T p.G72= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs200923670, COSV54206941; called by muse, mutect2, varscan2
- ZFYVE9 | c.1245A>T p.V415= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55098326; called by muse, varscan2
